Gene-level copy-number profile of tumor specimen TCGA-FI-A2CY-01A from TCGA case TCGA-FI-A2CY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,098 days).
Specimen TCGA-FI-A2CY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.29d427bd-1787-4eb6-9ffd-3dc6f752ef9e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FI-A2CY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/299fb9ab-ddef-4cbd-ac6f-a4d660a9ce89

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 13,965; copy number 2: 40,960; copy number 3: 4,554; copy number 4: 180; copy number 5: 38; copy number 6: 38; copy number 7: 2; copy number 22: 26; copy number 29: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FI-A2CY-01A-11D-A17C-01): tumor purity 0.83, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:99,158,416–99,272,197, 3 genes: AL162151.1, BCL11B, AL109767.1.
- chr19:23,762,944–24,129,968, 14 genes (within-gene range 0–1): AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 143 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:101,345,550–101,567,901, 8 genes, copy number 5: CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2.
- chr3:14,272,373–14,394,757, 3 genes, copy number 6–7 (within-gene range 4–7): AC093496.1, LINC01267, RNA5SP124.
- chr3:66,378,797–66,637,412, 3 genes, copy number 5 (within-gene range 2–5): LRIG1, AC104440.1, RPL21P41.
- chr3:187,932,764–188,154,057, 6 genes, copy number 5: AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 5: FLJ42393.
- chr3:197,042,560–198,222,513, 36 genes, copy number 6 (within-gene range 3–6): DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:38,276,178–38,523,180, 5 genes, copy number 5 (within-gene range 2–5): AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258.
- chr19:28,065,267–31,655,461, 66 genes, copy number 7–29 (broad region; genes not listed).
- chr22:39,570,753–40,410,289, 15 genes, copy number 5 (within-gene range 4–5): CACNA1I, ENTHD1, MTFR2P2, RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1.

Autosomal genes at a single copy (total copy number 1): 11,608. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
